Somatic mutation profile of tumor specimen TCGA-AX-A1C4-01A (aliquot TCGA-AX-A1C4-01A-11D-A135-09) from TCGA case TCGA-AX-A1C4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 52.6 years (19,209 days).
Specimen TCGA-AX-A1C4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d255728-b772-4fea-938d-714a1661eb9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1C4-10A (Blood Derived Normal), aliquot TCGA-AX-A1C4-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fba36f4-dd7c-4f4e-86a7-1ce7274cfe4e

The open-access MAF lists 1,035 somatic variants for this specimen: 791 protein-altering or splice-affecting, 221 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 502, Silent 221, Frame Shift Del 186, Nonsense Mutation 40, Frame Shift Ins 31, Splice Site 13, Splice Region 9, In Frame Del 7, Intron 7, 5'Flank 5, RNA 4, 3'Flank 3.

Variants (750 of 1,035; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ARSL | c.1442C>T p.T481M | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs80338713, CM030775, COSV101140517; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHRNA4 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs281865068, CM094469, COSV64719406; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, varscan2
- F8 | c.4379del p.N1460Ifs*5 | Frame Shift Del (DEL) | VAF 28/55 reads (51%) | catalogued as rs387906455, CD910498; ClinVar: pathogenic; called by mutect2, varscan2
- FGFR2 | c.1144T>C p.C382R | Missense Mutation (SNP) | VAF 35/62 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.536); catalogued as rs121913474, COSV60638681, COSV60642677; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 28/61 reads (46%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ITGB4 | c.600del p.F201Sfs*9 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | catalogued as rs752657203, COSV52322249, COSV52323301; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KMT2D | c.7411C>T p.R2471* | Nonsense Mutation (SNP) | VAF 17/25 reads (68%) | catalogued as rs1057518571, COSV56465022; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 32/60 reads (53%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- OFD1 | c.710del p.K237Sfs*6 | Frame Shift Del (DEL) | VAF 37/77 reads (48%) | catalogued as rs312262845; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1258T>C p.C420R | Missense Mutation (SNP) | VAF 8/11 reads (73%) | hotspot (GDC flag); SIFT tolerated (0.21); PolyPhen possibly damaging (0.908); catalogued as rs121913272, COSV55874020; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPARG | c.556del p.S186Vfs*47 (on ENST00000287820 / NM_015869.5; = p.S156Vfs*47 on NM_005037.7) | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | catalogued as rs587776687; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- SLC6A9 | c.1051C>T p.Q351* (on ENST00000360584 / NM_201649.4; = p.Q297* on NM_006934.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as rs201437896, COSV100746524; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2M | c.3799G>A p.A1267T | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.613); catalogued as COSV100589038; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs746497630; called by mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as rs770970036; called by mutect2, varscan2
- AASS | c.1304T>G p.L435R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100741885; called by muse, mutect2, varscan2
- ABCA8 | c.3206C>T p.A1069V | Missense Mutation (SNP) | VAF 40/63 reads (63%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as rs752567541, COSV99286948; called by muse, mutect2, varscan2
- ABCC1 | c.3361C>T p.P1121S | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100580363; called by muse, mutect2, varscan2
- ABCC3 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs151133677; called by muse, mutect2, varscan2
- ABHD13 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101024272, COSV65534568; called by muse, mutect2, varscan2
- ABO | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs1259797239, COSV101506007; called by muse, mutect2
- ABR | c.1427C>T p.T476I (on ENST00000302538 / NM_021962.5; = p.T439I on NM_001092.5) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV99348612; called by muse, mutect2, varscan2
- ABTB2 | c.1895A>G p.D632G | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1459326004, COSV100132180; called by muse, mutect2, varscan2
- AC004997.1 | c.953A>G p.D318G | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious, low confidence (0); catalogued as COSV99304969; called by muse, mutect2, varscan2
- AC020907.6 | c.103C>T p.H35Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV100032992, COSV59534853; called by muse, mutect2, varscan2
- ACAD10 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 23/46 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); catalogued as COSV100564634; called by muse, mutect2, varscan2
- ACO2 | c.1405G>A p.V469I | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.058); catalogued as rs202122407, COSV53442495; called by muse, mutect2, varscan2
- ACTR1B | c.1030G>A p.G344S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763957570, COSV100008198; called by muse, mutect2
- ADAMTS6 | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754136006; called by muse, mutect2, varscan2
- ADAMTSL3 | c.728-1G>T p.X243_splice | Splice Site (SNP) | VAF 7/65 reads (11%) | catalogued as COSV99721275; called by muse, mutect2, varscan2
- ADAR | c.2493G>T p.K831N | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.52); PolyPhen benign (0.368); catalogued as COSV52717980, COSV99426735; called by muse, varscan2
- ADARB1 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs142180298, COSV100654129; called by muse, mutect2, varscan2
- ADGRE3 | c.1694G>T p.W565L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53729726, COSV99506723; called by muse, mutect2, varscan2
- ADGRV1 | c.6344A>G p.D2115G | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); catalogued as COSV101316531; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | catalogued as rs761350619; called by mutect2, varscan2
- ADORA2B | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.808); catalogued as rs768369462, COSV100420065; called by muse, mutect2, varscan2
- AFM | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.39); PolyPhen benign (0.068); catalogued as rs200974972, COSV99889271; called by muse, mutect2, varscan2
- AGAP1 | c.2315C>T p.A772V (on ENST00000304032 / NM_001037131.3; = p.A719V on NM_014914.5) | Missense Mutation (SNP) | VAF 96/189 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.401); catalogued as rs1349751380, COSV58335314; called by muse, mutect2, varscan2
- AGFG1 | c.1319C>G p.A440G | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV59514012; called by muse, mutect2, varscan2
- AHNAK2 | c.7917G>T p.K2639N | Missense Mutation (SNP) | VAF 75/145 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.423); catalogued as COSV100318998; called by muse, mutect2, varscan2
- AKAP17A | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.91); catalogued as COSV100002507; called by muse, mutect2, varscan2
- ALDOC | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV52024551; called by muse, mutect2, varscan2
- ALPP | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs755793283, COSV101235192; called by muse, mutect2, varscan2
- ALYREF | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58668515; called by muse, mutect2, varscan2
- ANAPC1 | c.1408T>C p.S470P | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.353); catalogued as COSV100595108; called by muse, mutect2, varscan2
- ANK1 | c.5521G>A p.D1841N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as rs143987736; called by muse, mutect2, varscan2
- ANK1 | c.4136C>T p.P1379L | Missense Mutation (SNP) | VAF 66/131 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748160803, COSV55890290; called by muse, mutect2, varscan2
- AP2A1 | c.2342G>A p.G781D | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100571264; called by muse, mutect2, varscan2
- APEH | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs772175127, COSV99609876; called by muse, mutect2, varscan2
- APEH | c.1527del p.X509_splice | Splice Site (DEL) | VAF 36/85 reads (42%) | catalogued as rs1255876232; called by mutect2, pindel, varscan2
- APLP1 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.439); catalogued as rs1330917042, COSV99697950; called by muse, mutect2, varscan2
- ARHGAP28 | c.1900C>T p.R634* (on ENST00000383472 / NM_001366230.1; = p.R475* on NM_001010000.3) | Nonsense Mutation (SNP) | VAF 25/55 reads (45%) | catalogued as rs773098375, COSV51644954; called by muse, mutect2, varscan2
- ARHGEF10 | c.1871C>T p.A624V (on ENST00000398564; = p.A599V on NM_014629.4) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751343708, COSV100035654; called by muse, mutect2, varscan2
- ARHGEF12 | c.269A>T p.N90I | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1463008727, COSV100755214; called by muse, mutect2, varscan2
- ARHGEF17 | c.2791C>T p.H931Y | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.439); catalogued as COSV99736820; called by muse, mutect2, varscan2
- ARID3C | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748000904, COSV99427058; called by muse, mutect2, varscan2
- ARMCX5 | c.97A>C p.K33Q | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99863556; called by muse, mutect2, varscan2
- ARNTL2 | c.848dup p.C284Lfs*7 | Frame Shift Ins (INS) | VAF 20/44 reads (45%) | catalogued as rs1373896121; called by mutect2, varscan2
- ARSA | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1410667898, COSV99332507; called by muse, mutect2, varscan2
- ARV1 | c.518del p.K173Sfs*8 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | catalogued as rs544784472, COSV59618356; called by mutect2, varscan2
- ASPM | c.10415C>T p.T3472M | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1331602460, COSV99661152; called by muse, mutect2, varscan2
- ATP10B | c.3200A>G p.D1067G | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV100515785; called by muse, mutect2, varscan2
- ATP1A2 | c.1709C>T p.T570M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.602); catalogued as rs758815329, COSV63406017; called by muse, mutect2, varscan2
- ATP2B3 | c.2560C>T p.Q854* | Nonsense Mutation (SNP) | VAF 14/90 reads (16%) | catalogued as COSV54864051; called by muse, varscan2
- ATP6V0A4 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 42/78 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1298220188, COSV100023081, COSV100023699; called by muse, mutect2, varscan2
- ATP8B1 | c.1403del p.K468Sfs*23 | Frame Shift Del (DEL) | VAF 37/113 reads (33%) | catalogued as COSV99376641; called by mutect2, pindel, varscan2
- ATR | c.2638G>A p.A880T | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs367864862, COSV63391214; called by muse, varscan2
- ATXN7L2 | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs772481589, COSV100149952; called by muse, mutect2, varscan2
- B3GNT6 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs782344607, COSV62828263, COSV62828543; called by muse, mutect2, varscan2
- B4GALT2 | c.358C>T p.R120W | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs746681353, COSV52542791; called by muse, mutect2, varscan2
- BACE2 | c.305del p.P102Rfs*25 | Frame Shift Del (DEL) | VAF 24/91 reads (26%) | catalogued as rs771098505; called by mutect2, pindel, varscan2
- BCL6B | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV99546929; called by muse, mutect2, varscan2
- BICRA | c.3283G>A p.V1095I | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs910282287, COSV67605863, COSV67606811; called by muse, mutect2, varscan2
- BMP4 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55415439; called by muse, mutect2, varscan2
- BMPR1A | c.625C>A p.L209I | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100923712; called by muse, mutect2, varscan2
- BNIP5 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs758606753, COSV101465217; called by muse, mutect2, varscan2
- BOD1L1 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99238332, COSV99240454; called by muse, mutect2, varscan2
- BRD3 | c.71del p.P24Rfs*24 | Frame Shift Del (DEL) | VAF 18/50 reads (36%) | catalogued as rs763134487; called by mutect2, varscan2
- BRD4 | c.1192A>G p.M398V | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99651439; called by muse, mutect2, varscan2
- BRSK1 | c.1135del p.R379Gfs*9 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | catalogued as rs746043904, COSV58665984; called by mutect2, varscan2
- BTF3L4 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs1316061849, COSV100511243; called by muse, mutect2
- BTK | c.1913C>T p.A638V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV100437934; called by muse, mutect2, varscan2
- C11orf24 | c.911G>C p.S304T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as COSV100422734, COSV58505154; called by muse, mutect2, varscan2
- C11orf49 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 24/48 reads (50%) | catalogued as rs758530873, COSV99562833, COSV99562890; called by muse, mutect2, varscan2
- C1orf216 | c.281A>G p.E94G | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV99231545; called by muse, mutect2, varscan2
- C20orf85 | c.269del p.P90Qfs*19 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | catalogued as rs777635732, COSV100959338, COSV64519981; called by mutect2, pindel, varscan2
- C5 | c.4007G>T p.R1336M | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV99798753; called by muse, mutect2
- C6 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs544678725, COSV54708806; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, pindel, varscan2
- C9orf43 | c.719T>C p.M240T | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV99928602; called by muse, mutect2, varscan2
- CABIN1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99574057; called by muse, mutect2, varscan2
- CACHD1 | c.2738C>T p.T913M | Missense Mutation (SNP) | VAF 53/125 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs182391558, COSV51547812; called by muse, mutect2, varscan2
- CACNA1C | c.3386C>T p.T1129M | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.058); catalogued as rs374549078; called by muse, mutect2, varscan2
- CAD | c.2197G>A p.V733M | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs746384341, COSV99255758; called by muse, mutect2, varscan2
- CADM3 | c.715C>T p.P239S (on ENST00000368125 / NM_001127173.3; = p.P273S on NM_021189.5) | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as COSV63686120; called by muse, mutect2, varscan2
- CADPS2 | c.2455A>G p.T819A | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.318); catalogued as COSV57385148; called by muse, mutect2, varscan2
- CAMSAP1 | c.4460G>A p.C1487Y | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100410453; called by muse, mutect2, varscan2
- CAPN15 | c.2278C>T p.R760C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201195272; called by muse, mutect2, varscan2
- CBL | c.1580T>G p.L527R | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.079); catalogued as COSV99877076; called by muse, mutect2
- CC2D1B | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as rs745401046, COSV52562698; called by muse, mutect2, varscan2
- CCDC114 | c.1846G>A p.V616M | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as rs780679601, COSV100197111; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC124 | c.302A>C p.E101A | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0.228); catalogued as COSV101506514; called by muse, mutect2, varscan2
- CCDC18 | c.1770G>C p.K590N (on ENST00000343253 / NM_001306076.1; = p.K591N on NM_206886.4) | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100159984; called by muse, mutect2, varscan2
- CCDC54 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs865960669, COSV53758380, COSV53758641; called by muse, mutect2, varscan2
- CCND1 | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs779733976, COSV57121564; called by muse, varscan2
- CCND1 | c.855C>A p.C285* | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as COSV99919854; called by muse, varscan2
- CD164 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.823); catalogued as rs866904774, COSV99248937; called by muse, mutect2, varscan2
- CDC42BPB | c.4444T>A p.Y1482N | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV100775620; called by muse, mutect2, varscan2
- CDC42BPG | c.3847G>A p.V1283M | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs746735742, COSV100712163; called by muse, mutect2, varscan2
- CDCA4 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs375561549; called by muse, mutect2, varscan2
- CDH10 | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1299821656, COSV52574699, COSV52578909; called by muse, mutect2, varscan2
- CDH19 | c.1697T>G p.L566R | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100052377; called by muse, mutect2, varscan2
- CDH20 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99406572; called by muse, mutect2, varscan2
- CDHR2 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as rs149280788; called by muse, mutect2, varscan2
- CDK5RAP3 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs751198396, COSV58114385; called by muse, mutect2, varscan2
- CDX2 | c.916del p.V306Cfs*2 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs773511514; called by mutect2, pindel, varscan2
- CELSR1 | c.7505G>A p.S2502N | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV99420079; called by muse, mutect2, varscan2
- CELSR1 | c.5544del p.T1849Rfs*8 | Frame Shift Del (DEL) | VAF 45/108 reads (42%) | catalogued as rs776824429; called by mutect2, pindel, varscan2
- CELSR1 | c.2231T>C p.I744T | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99420081; called by muse, mutect2, varscan2
- CELSR3 | c.6412T>C p.W2138R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99375046; called by muse, mutect2, varscan2
- CENPBD1 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.166); catalogued as COSV99240761; called by muse, mutect2, varscan2
- CENPP | c.519del p.F173Lfs*46 | Frame Shift Del (DEL) | VAF 38/81 reads (47%) | catalogued as rs750494120; called by mutect2, varscan2
- CEP350 | c.6560C>T p.A2187V | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100855258; called by muse, mutect2, varscan2
- CHAF1B | c.869C>T p.A290V | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV58440625; called by muse, mutect2, varscan2
- CHERP | c.1362del p.W455Gfs*200 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | catalogued as rs770045437; called by mutect2, pindel, varscan2
- CHGA | c.925A>G p.M309V | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV99381304; called by muse, mutect2, varscan2
- CHMP1B | c.289A>G p.K97E | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV99304222; called by muse, mutect2, varscan2
- CHRM3 | c.1025C>A p.A342D | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.589); catalogued as COSV99699503; called by muse, mutect2, varscan2
- CHRNB4 | c.325C>T p.R109C | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs746284415, COSV55715540; called by muse, mutect2, varscan2
- CKAP5 | c.4132C>T p.R1378C | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100371469; called by muse, mutect2, varscan2
- CLASP2 | c.3523C>T p.R1175C (on ENST00000359576; = p.R1174C on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1017768054, COSV56295719; called by muse, mutect2, varscan2
- CLASRP | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99673156; called by muse, mutect2, varscan2
- CLCA4 | c.218del p.F73Sfs*7 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs745822656; called by mutect2, varscan2
- CLDN23 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1327578278, COSV101093188; called by muse, mutect2, varscan2
- CLEC4F | c.194G>A p.R65K | Missense Mutation (SNP) | VAF 68/128 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.045); catalogued as rs1179637918, COSV99713651, COSV99714019; called by muse, varscan2
- CLIP4 | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV60750908; called by muse, mutect2, varscan2
- CLOCK | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs1287312825, COSV59401787; called by muse, mutect2, varscan2
- CLPTM1L | c.1240G>A p.G414R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1205734087, COSV57990739; called by muse, mutect2, varscan2
- CMTM6 | c.213del p.F71Lfs*4 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs1167303901; called by mutect2, pindel
- CNGA2 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV61705810; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 27/55 reads (49%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CNTN1 | c.112G>T p.G38* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV104418046, COSV61636015; called by muse, mutect2, varscan2
- CNTNAP1 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.722); catalogued as rs530020899, COSV99227039; called by muse, mutect2, varscan2
- CNTRL | c.3168+2T>A p.X1056_splice | Splice Site (SNP) | VAF 28/60 reads (47%) | catalogued as COSV99443906; called by muse, mutect2, varscan2
- COG1 | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs374792279; called by muse, mutect2, varscan2
- COG2 | c.899G>T p.S300I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100794801; called by muse, mutect2, varscan2
- COL18A1 | c.4289del p.P1430Lfs*16 (on ENST00000359759 / NM_130444.3; = p.P1195Lfs*16 on NM_030582.4) | Frame Shift Del (DEL) | VAF 12/61 reads (20%) | catalogued as rs748210520; called by mutect2, pindel, varscan2
- COL22A1 | c.3001C>A p.L1001I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.042); catalogued as COSV57332797; called by muse, mutect2, varscan2
- COPA | c.2355C>T p.I785= | Splice Region (SNP) | VAF 36/66 reads (55%) | catalogued as COSV99616835; called by muse, mutect2, varscan2
- COPE | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 21/154 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs772579113, COSV53233161; called by muse, mutect2, varscan2
- CORO7 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs201907324, COSV99228152; called by muse, mutect2, varscan2
- CPLANE2 | c.656A>G p.D219G | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV100983289; called by muse, mutect2, varscan2
- CRKL | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100574209; called by muse, mutect2, varscan2
- CRNN | c.500A>G p.Y167C | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as COSV55124070; called by muse, mutect2, varscan2
- CRYBB2 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 12/58 reads (21%) | catalogued as COSV101236777; called by muse, mutect2, varscan2
- CSRNP2 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs144820964; called by muse, mutect2, varscan2
- CTBP2 | c.1168G>T p.G390C | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV100456935; called by muse, mutect2, varscan2
- CTNND1 | c.2620G>A p.D874N (on ENST00000399050 / NM_001085458.2; = p.D868N on NM_001331.3) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV100650296; called by muse, mutect2
- CUBN | c.83T>C p.L28P | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1054077052, COSV100910672; called by muse, mutect2, varscan2
- CYB5R4 | c.115C>T p.R39* | Nonsense Mutation (SNP) | VAF 36/82 reads (44%) | catalogued as rs1320230000, COSV63745864, COSV63746888; called by muse, mutect2, varscan2
- CYP2B6 | c.1152G>T p.K384N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100137801; called by muse, mutect2, varscan2
- CYP2U1 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV100256823; called by muse, mutect2, varscan2
- CYP2W1 | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs200372185, COSV100417327; called by muse, varscan2
- CYP8B1 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 34/59 reads (58%) | catalogued as rs372757086; called by muse, mutect2, varscan2
- DCAKD | c.373A>G p.K125E | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV100149606; called by muse, mutect2, varscan2
- DDX21 | c.2273G>A p.R758Q | Missense Mutation (SNP) | VAF 34/51 reads (67%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.011); catalogued as rs1359628594, COSV62557088; called by muse, mutect2, varscan2
- DEF6 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1043201299, COSV100359535; called by muse, mutect2, varscan2
- DEPDC5 | c.767+2T>C p.X256_splice | Splice Site (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99836618; called by muse, mutect2
- DGKZ | c.3110dup p.E1038Rfs*4 (on ENST00000454345 / NM_001105540.2; = p.E850Rfs*4 on NM_003646.4) | Frame Shift Ins (INS) | VAF 12/48 reads (25%) | catalogued as rs3832759; called by mutect2, varscan2
- DIDO1 | c.6101del p.P2034Rfs*240 | Frame Shift Del (DEL) | VAF 29/47 reads (62%) | catalogued as COSV56634983; called by mutect2, pindel, varscan2
- DIDO1 | c.3963_3964del p.F1322Wfs*52 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | catalogued as rs781631041; called by pindel, varscan2
- DNAAF4 | c.961A>G p.N321D | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as COSV100336937; called by muse, mutect2, varscan2
- DNER | c.1372C>A p.P458T | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.13); catalogued as COSV100520096; called by muse, mutect2, varscan2
- DNMBP | c.2854A>G p.N952D | Missense Mutation (SNP) | VAF 60/182 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.056); catalogued as COSV100144453; called by muse, mutect2
- DOCK10 | c.1272del p.F424Lfs*2 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs1559599687; called by pindel, varscan2
- DOCK5 | c.4713dup p.T1572Yfs*10 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs745668075; called by mutect2, varscan2
- DPAGT1 | c.698dup p.T234Hfs*116 | Frame Shift Ins (INS) | VAF 22/54 reads (41%) | catalogued as rs35482889; called by mutect2, varscan2
- DPYSL5 | c.1609G>T p.G537C | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99982815; called by muse, mutect2, varscan2
- DSCAM | c.2015G>A p.R672Q | Missense Mutation (SNP) | VAF 40/64 reads (63%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs148397235, COSV68031793; called by muse, mutect2, varscan2
- DTNB | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99978052; called by muse, mutect2, varscan2
- DTX2 | c.442del p.L148Wfs*35 | Frame Shift Del (DEL) | VAF 47/122 reads (39%) | catalogued as rs1376725973; called by mutect2, pindel, varscan2
- DYNC2H1 | c.2422G>A p.G808S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372055203; called by muse, mutect2, varscan2
- EBPL | c.516del p.F172Lfs*7 | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | catalogued as rs369293935; called by mutect2, varscan2
- ECD | c.1191A>G p.I397M | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV100881506; called by muse, mutect2, varscan2
- EFNB3 | c.179T>C p.L60P | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99872985; called by muse, mutect2
- EGR4 | c.995del p.P332Rfs*7 (on ENST00000545030; = p.P229Rfs*7 on NM_001965.4) | Frame Shift Del (DEL) | VAF 34/95 reads (36%) | catalogued as COSV104436788; called by mutect2, pindel, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 24/55 reads (44%) | catalogued as rs748937918; called by mutect2, varscan2
- EMC1 | c.2461G>A p.A821T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.058); catalogued as rs1296201536, COSV64345258; called by muse, mutect2
- EMILIN1 | c.2186G>A p.R729H | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs144332637; called by muse, mutect2, varscan2
- ENG | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs780987528, COSV100785347; ClinVar: uncertain significance; called by muse, varscan2
- ENPP1 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1174599759, COSV100719653; called by muse, varscan2
- EOLA2 | c.254-1G>C p.X85_splice | Splice Site (SNP) | VAF 42/86 reads (49%) | catalogued as COSV100778131; called by muse, mutect2, varscan2
- EP400 | c.7767G>A p.M2589I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.093); catalogued as COSV100202324; called by muse, mutect2, varscan2
- EPHA3 | c.907A>G p.N303D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1291352437, COSV100348895, COSV60700401; called by muse, mutect2, varscan2
- EPHB1 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs959853730, COSV67657761; called by muse, mutect2, varscan2
- EPHX4 | c.907T>C p.W303R | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100952774; called by muse, mutect2, varscan2
- EPPK1 | c.6632T>C p.M2211T | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.64); PolyPhen benign (0.019); catalogued as rs782069104, COSV101599957; called by muse, mutect2
- EPPK1 | c.4223C>T p.A1408V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs368940625; called by muse, mutect2, varscan2
- EPRS1 | c.3060del p.E1021Kfs*17 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | catalogued as rs1394740497; called by mutect2, pindel, varscan2
- EPS8L2 | c.1816G>C p.A606P | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.08); PolyPhen benign (0.133); catalogued as COSV100585749; called by muse, mutect2, varscan2
- EPS8L2 | c.1817C>T p.A606V | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1193769875, COSV100585750; called by muse, mutect2, varscan2
- ERN2 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1296136471, COSV55624146; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | catalogued as rs775950025; called by mutect2, varscan2
- ETAA1 | c.2740C>T p.R914* | Nonsense Mutation (SNP) | VAF 31/55 reads (56%) | catalogued as COSV99712952; called by muse, mutect2, varscan2
- EVI5 | c.1222del p.M408* | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs760182064; called by mutect2, varscan2
- EVX2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100420850, COSV57962960; called by muse, mutect2, varscan2
- EWSR1 | c.1865del p.P622Lfs*4 | Frame Shift Del (DEL) | VAF 29/74 reads (39%) | catalogued as COSV58427582; called by mutect2, pindel, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 25/80 reads (31%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM20A | c.907_908del p.S303Cfs*76 | Frame Shift Del (DEL) | VAF 44/192 reads (23%) | catalogued as rs750880244; called by pindel, varscan2
- FAM219A | c.492del p.K165Sfs*3 (on ENST00000445726; = p.K148Sfs*3 on NM_147202.2 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 23/50 reads (46%) | catalogued as rs760074479; called by mutect2, pindel, varscan2
- FAM24A | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100925091; called by muse, mutect2, varscan2
- FASN | c.2065G>A p.A689T | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as rs999063855, COSV100148334; called by muse, mutect2, varscan2
- FAXDC2 | c.338A>G p.Y113C | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100394328; called by muse, mutect2, varscan2
- FBXW4 | c.959A>T p.D320V | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100489596; called by muse, mutect2, varscan2
- FBXW9 | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100790418; called by muse, mutect2, varscan2
- FGA | c.1960G>T p.G654* | Nonsense Mutation (SNP) | VAF 28/55 reads (51%) | catalogued as COSV100120751; called by muse, mutect2, varscan2
- FKBP6 | c.359C>T p.T120M | Missense Mutation (SNP) | VAF 89/203 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.663); catalogued as rs200493820; called by muse, mutect2, varscan2
- FMO5 | c.779dup p.I261Dfs*6 | Frame Shift Ins (INS) | VAF 13/77 reads (17%) | catalogued as rs72549315; called by mutect2, varscan2
- FPGT-TNNI3K | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs773659191, COSV100438092; called by muse, mutect2, varscan2
- FUT11 | c.770C>A p.T257K | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.707); catalogued as rs751407484, COSV59542846; called by muse, mutect2, varscan2
- FZD4 | c.487G>T p.G163C | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV101536077; called by muse, mutect2, varscan2
- GAB2 | c.1561C>T p.R521W (on ENST00000361507 / NM_080491.3; = p.R483W on NM_012296.3) | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs763198440, COSV60868031; called by muse, mutect2, varscan2
- GABBR1 | c.554del p.G185Afs*15 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | catalogued as COSV63541455; called by mutect2, varscan2
- GDA | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99429854; called by muse, mutect2, varscan2
- GINS3 | c.550A>G p.N184D | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.021); catalogued as COSV100139405; called by muse, mutect2, varscan2
- GIT2 | c.1027G>A p.A343T (on ENST00000355312 / NM_057169.5; = p.A345T on NM_014776.5) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.781); catalogued as rs1358646788, COSV100189317; called by muse, mutect2, varscan2
- GJA4 | c.593G>A p.C198Y | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100654769; called by muse, mutect2, varscan2
- GLI4 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs761788760, COSV100390819, COSV100391199; called by muse, mutect2, varscan2
- GNAS | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); catalogued as CM131321, CM152413, COSV99671060; called by muse, mutect2, varscan2
- GOLIM4 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752798300, COSV100463496; called by muse, mutect2, varscan2
- GP5 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV59879118; called by muse, mutect2, varscan2
- GP5 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55464158; called by muse, mutect2, varscan2
- GPAA1 | c.530C>G p.A177G | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100284219; called by muse, mutect2, varscan2
- GPATCH8 | c.1466A>G p.D489G | Missense Mutation (SNP) | VAF 68/105 reads (65%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100132875; called by muse, mutect2, varscan2
- GPR148 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.175); catalogued as COSV99998747, COSV99998769; called by muse, mutect2, varscan2
- GPR52 | c.689G>A p.C230Y | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99274319; called by muse, mutect2, varscan2
- GPR63 | c.1147C>A p.L383M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.391); catalogued as COSV100013576; called by muse, mutect2, varscan2
- GPRASP1 | c.3577C>T p.R1193* | Nonsense Mutation (SNP) | VAF 26/71 reads (37%) | catalogued as COSV64356027; called by muse, mutect2, varscan2
- GPRC5C | c.1204C>T p.P402S (on ENST00000652232; = p.P357S on NM_018653.4) | Missense Mutation (SNP) | VAF 71/113 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100703011; called by muse, mutect2, varscan2
- GRB10 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs993924030, COSV60010362; called by muse, mutect2, varscan2
- GRIA1 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs781643218, COSV99599262; called by muse, mutect2, varscan2
- GRIA4 | c.2417C>T p.T806M | Missense Mutation (SNP) | VAF 86/162 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV56893686; called by muse, mutect2, varscan2
- GRID1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 61/190 reads (32%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.931); catalogued as rs1169877155, COSV100026654; called by muse, mutect2, varscan2
- GRIK1 | c.2130+2T>C p.X710_splice | Splice Site (SNP) | VAF 28/73 reads (38%) | catalogued as COSV100518007; called by muse, mutect2, varscan2
- GRIK3 | c.1525G>A p.D509N | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs746494649, COSV66138660; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 57/118 reads (48%) | catalogued as rs754199513; called by mutect2, varscan2
- GTF2IRD2 | c.1384C>A p.L462I | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as COSV100736471; called by muse, mutect2, varscan2
- GUSB | c.1180C>T p.Q394* | Nonsense Mutation (SNP) | VAF 17/50 reads (34%) | catalogued as COSV59221814; called by muse, mutect2, varscan2
- GZF1 | c.226A>G p.N76D | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.239); catalogued as COSV100582676; called by muse, mutect2, varscan2
- GZMM | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as COSV99198874; called by muse, mutect2, varscan2
- H2AC16 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); catalogued as rs1177803561, COSV58901606; called by muse, mutect2, varscan2
- H3C10 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV100297682; called by muse, mutect2, varscan2
- H4C13 | c.53G>A p.R18H | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0.04); catalogued as COSV100137945; called by muse, mutect2, varscan2
- HAL | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99701665; called by muse, mutect2, varscan2
- HAS1 | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.029); catalogued as COSV55786797; called by muse, mutect2, varscan2
- HBP1 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 50/103 reads (49%) | catalogued as COSV56017606, COSV99753592; called by muse, mutect2, varscan2
- HBP1 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99753595; called by muse, mutect2
- HCFC1 | c.3913G>A p.A1305T | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.013); catalogued as COSV60071491; called by muse, mutect2
- HCN2 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs746499730, COSV52118544; called by muse, mutect2, varscan2
- HECW1 | c.2996G>A p.R999H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs372121389, COSV67838145; called by muse, mutect2, varscan2
- HEG1 | c.875G>T p.R292M | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100230950; called by muse, mutect2, varscan2
- HELQ | c.1022A>G p.H341R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV99788157; called by muse, mutect2, varscan2
- HELZ | c.4828G>A p.V1610I | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs201043728; called by muse, mutect2, varscan2
- HEPH | c.77G>A p.R26Q (on ENST00000343002; = p.R80Q on NM_138737.5) | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745974085, COSV100295755; called by muse, mutect2, varscan2
- HIPK2 | c.3580C>A p.Q1194K | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101301662; called by muse, mutect2, varscan2
- HK1 | c.403G>C p.G135R | Missense Mutation (SNP) | VAF 99/144 reads (69%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.666); catalogued as COSV100067998; called by muse, mutect2, varscan2
- HLA-DOA | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs565438950, COSV57714546; called by muse, mutect2
- HNRNPF | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 58/84 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV100563326; called by muse, mutect2, varscan2
- HPDL | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.144); catalogued as COSV58343535; called by muse, mutect2, varscan2
- HPS3 | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 69/147 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV99937652; called by muse, mutect2, varscan2
- HSD17B8 | c.388-1G>T p.X130_splice | Splice Site (SNP) | VAF 33/62 reads (53%) | catalogued as COSV100761866; called by muse, mutect2, varscan2
- HSPB8 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs768405176, COSV56139153, COSV99931441, COSV99931504; called by muse, mutect2, varscan2
- HTT | c.8512T>C p.Y2838H | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100751267; called by muse, mutect2, varscan2
- HYAL1 | c.1158T>A p.S386R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.144); catalogued as COSV99807908; called by muse, mutect2, varscan2
- IGSF8 | c.1366del p.E456Rfs*45 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs760022485; called by mutect2, varscan2
- IKBKB | c.1939C>T p.Q647* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV100645843; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV100150624; called by muse, mutect2, varscan2
- IL6ST | c.1358A>G p.Y453C | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1237217584, COSV100411058; called by muse, mutect2, varscan2
- INF2 | c.2026C>A p.L676I | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.285); catalogued as COSV99384402; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 16/70 reads (23%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IQSEC1 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1362238013, COSV99831405; called by muse, mutect2, varscan2
- IRF2BP2 | c.1672G>A p.V558M | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747870654, COSV100784279; called by muse, mutect2, varscan2
- IRF9 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201638725; called by muse, mutect2, varscan2
- ISG20L2 | c.50del p.K17Rfs*3 | Frame Shift Del (DEL) | VAF 38/86 reads (44%) | catalogued as rs35218759, COSV100493966; called by mutect2, pindel, varscan2
- ITGA6 | c.894T>G p.G298= (on ENST00000442250; = p.G259= on NM_000210.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 59/125 reads (47%) | catalogued as COSV99906116; called by muse, mutect2, varscan2
- ITPR3 | c.3170G>A p.R1057H | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs763191989, COSV65415126; called by muse, mutect2, varscan2
- ITPR3 | c.4165T>C p.S1389P | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100968150; called by muse, mutect2, varscan2
- ITPRIPL2 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as rs751568618, COSV101198238; called by muse, mutect2, varscan2
- JADE1 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs1362304065, COSV99885498; called by muse, mutect2, varscan2
- JAK1 | c.1753C>T p.Q585* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV100692457; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 35/78 reads (45%) | catalogued as rs755650243; called by mutect2, varscan2
- JMJD1C | c.6075del p.E2026Kfs*45 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | catalogued as rs1226801045; called by mutect2, varscan2
- JMJD1C | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 48/75 reads (64%) | catalogued as COSV101232480; called by muse, mutect2, varscan2
- KALRN | c.325A>G p.K109E | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99567398; called by muse, mutect2, varscan2
- KALRN | c.6028A>G p.K2010E (on ENST00000360013 / NM_001024660.4; = p.K313E on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV99362999; called by muse, mutect2, varscan2
- KAT6A | c.5666G>A p.R1889H | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs1342950357, COSV99705915; ClinVar: likely benign; called by muse, mutect2, varscan2
- KBTBD4 | c.1060G>T p.G354C | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.315); catalogued as COSV100442966; called by muse, mutect2, varscan2
- KCNF1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs773222597, COSV54462551; called by muse, mutect2, varscan2
- KCNK15 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.43); PolyPhen benign (0.106); catalogued as COSV100865852; called by muse, mutect2, varscan2
- KCNS2 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.421); catalogued as COSV99751475; called by muse, mutect2, varscan2
- KCTD5 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.212); catalogued as rs368186661; called by muse, varscan2
- KIAA0232 | c.2353del p.T785Hfs*4 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs1560202607; called by mutect2, varscan2
- KIF13A | c.1714G>A p.A572T | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.521); catalogued as COSV99438240; called by muse, mutect2, varscan2
- KIF18B | c.550G>T p.V184L | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV100192597; called by muse, mutect2, varscan2
- KIF24 | c.1982dup p.P662Afs*10 | Frame Shift Ins (INS) | VAF 30/55 reads (55%) | catalogued as rs570788521; called by mutect2, varscan2
- KIF26B | c.3959G>A p.S1320N | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1464051758, COSV100833468; called by muse, mutect2, varscan2
- KLC2 | c.1355T>C p.L452P | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100270884; called by muse, mutect2, varscan2
- KLF11 | c.1036G>T p.G346* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100007921; called by muse, mutect2, varscan2
- KLF3 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.698); catalogued as rs766351747, COSV99789973; called by muse, varscan2
- KLK12 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767936758, COSV99142090; called by muse, mutect2, varscan2
- KLRC4 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as rs772823809, COSV100511354; called by muse, mutect2, varscan2
- KMT2B | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 60/140 reads (43%) | catalogued as COSV52890581; called by muse, mutect2, varscan2
- KMT2B | c.8060C>A p.T2687N | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99495446; called by muse, mutect2, varscan2
- KMT2C | c.3947C>A p.P1316H | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.754); catalogued as COSV100076614; called by muse, mutect2
- KPNA6 | c.645A>G p.L215= | Splice Region (SNP) | VAF 37/80 reads (46%) | catalogued as rs1458744233, COSV101012628; called by muse, mutect2, varscan2
- KRTAP10-7 | c.296G>A p.C99Y | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs782066975, COSV100170333; called by muse, mutect2, varscan2
- KRTAP17-1 | c.218del p.G73Vfs*41 | Frame Shift Del (DEL) | VAF 49/114 reads (43%) | catalogued as rs1467971322; called by pindel, varscan2
- KRTAP19-8 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as rs745395071, COSV101239218; called by muse, mutect2, varscan2
- KRTAP6-3 | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 245/377 reads (65%) | catalogued as COSV66962737; called by muse, mutect2, varscan2
- KSR1 | c.2422A>G p.I808V (on ENST00000644974 / NM_001367810.1; = p.I693V on NM_014238.2) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs779236106, COSV99260877; called by muse, mutect2, varscan2
- LAMA5 | c.10306C>T p.R3436W | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs527914113, COSV99442379; called by muse, varscan2
- LENG8 | c.1847G>A p.R616H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV58725914; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 29/66 reads (44%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LPO | c.1324A>T p.I442L | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.053); catalogued as COSV99229422; called by muse, mutect2, varscan2
- LRCH3 | c.447T>A p.N149K | Missense Mutation (SNP) | VAF 66/136 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as COSV100605269; called by muse, mutect2, varscan2
- LRRC47 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.265); catalogued as rs1468850477, COSV100989383; called by muse, mutect2, varscan2
- LRRC49 | c.1778G>A p.S593N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1432291959, COSV99538226; called by muse, mutect2, varscan2
- LTF | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs201923778; called by muse, mutect2, varscan2
- LYSMD1 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100925229; called by muse, mutect2, varscan2
- LZTS2 | c.124C>G p.P42A | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV64651079, COSV64651396; called by muse, mutect2, varscan2
- MAFG | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 32/42 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV100155754; called by muse, mutect2, varscan2
- MAGEC2 | c.156del p.S53Lfs*9 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as COSV99909512; called by mutect2, pindel, varscan2
- MAN2A1 | c.580T>C p.Y194H | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99811940; called by muse, mutect2, varscan2
- MAP1B | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99702951; called by muse, mutect2, varscan2
- MAP1LC3A | c.355T>C p.F119L | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV99466888; called by muse, mutect2, varscan2
- MAP3K12 | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57236106; called by muse, mutect2, varscan2
- MAP4K2 | c.1303C>T p.P435S | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs368722505, COSV53650396; called by muse, mutect2, varscan2
- MBD4 | c.939del p.E314Kfs*4 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | catalogued as rs558765093; called by mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | catalogued as rs762648935; called by mutect2, pindel, varscan2
- MCM3AP | c.4030C>T p.P1344S | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV99387541; called by muse, mutect2
- MCTP2 | c.2264del p.K755Rfs*3 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | catalogued as rs1213053638; called by mutect2, pindel, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 12/20 reads (60%) | catalogued as rs1180255648; called by mutect2, varscan2
- MDN1 | c.6338C>A p.P2113H | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.852); catalogued as COSV101021842; called by muse, mutect2, varscan2
- ME1 | c.1025A>G p.K342R | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.787); catalogued as COSV100866701; called by muse, mutect2, varscan2
- MED12 | c.4811G>A p.G1604D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV100380027; called by muse, mutect2, varscan2
- MED4 | c.811T>C p.*271Rext*10 | Nonstop Mutation (SNP) | VAF 50/94 reads (53%) | catalogued as COSV99320081; called by muse, mutect2, varscan2
- MEGF10 | c.2359C>T p.Q787* | Nonsense Mutation (SNP) | VAF 9/91 reads (10%) | catalogued as rs779401235, COSV99175686; called by muse, mutect2, varscan2
- MERTK | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 93/174 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.594); catalogued as rs369655379; called by muse, mutect2, varscan2
- METTL2B | c.1115C>A p.P372H | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99300013; called by muse, mutect2, varscan2
- MFGE8 | c.149T>C p.F50S | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV99183985; called by muse, mutect2, varscan2
- MFN2 | c.306del p.F102Lfs*11 | Frame Shift Del (DEL) | VAF 12/69 reads (17%) | catalogued as rs777012596; called by mutect2, pindel, varscan2
- MGAM | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs377442966; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MIS18A | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.067); catalogued as COSV51590609; called by muse, mutect2, varscan2
- MIS18BP1 | c.471del p.K157Nfs*24 | Frame Shift Del (DEL) | VAF 66/106 reads (62%) | catalogued as rs546807245; called by mutect2, varscan2
- MLF2 | c.668G>T p.R223M | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as COSV99180117; called by muse, mutect2
- MLPH | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs752369818, COSV52821345; called by muse, mutect2, varscan2
- MMS22L | c.3038A>G p.Q1013R | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99247773; called by muse, mutect2, varscan2
- MRPL44 | c.158G>A p.C53Y | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV99285326; called by muse, mutect2, varscan2
- MTMR11 | c.2095A>T p.I699F (on ENST00000439741 / NM_001145862.2; = p.I627F on NM_181873.3) | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99641434; called by muse, mutect2, varscan2
- MTNR1B | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs766104801, COSV99925365; called by muse, mutect2, varscan2
- MUC5B | c.5027C>T p.T1676M | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as rs555536642, COSV71594616; called by muse, mutect2, varscan2
- MUC5B | c.8567G>A p.S2856N | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.065); catalogued as COSV101500782; called by muse, mutect2, varscan2
- MYBBP1A | c.3460G>A p.A1154T | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99627018; called by muse, mutect2, varscan2
- MYH11 | c.2392C>T p.R798C | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779195096, COSV55543958; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7B | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV99483318; called by muse, mutect2, varscan2
- MYL2 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV99960891; called by muse, mutect2, varscan2
- MYO1D | c.2935G>A p.V979I | Missense Mutation (SNP) | VAF 60/93 reads (65%) | SIFT tolerated (0.57); PolyPhen benign (0.021); catalogued as COSV100532165; called by muse, mutect2, varscan2
- MYO1F | c.3046G>A p.A1016T | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); catalogued as COSV100597098; called by muse, mutect2, varscan2
- MYO3A | c.4335dup p.L1446Ifs*3 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | catalogued as rs772558362; called by mutect2, pindel, varscan2
- NAXD | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.459); catalogued as rs1290048682, COSV57286429, COSV57290662; called by muse, mutect2, varscan2
- NBR1 | c.2893C>T p.R965C | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759599741, COSV57832657; called by muse, mutect2, varscan2
- NCAPD3 | c.2725del p.Q909Rfs*10 | Frame Shift Del (DEL) | VAF 7/48 reads (15%) | catalogued as rs770284236; called by mutect2, pindel, varscan2
- NCAPD3 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV101596380; called by muse, mutect2, varscan2
- NCBP1 | c.1703+2T>C p.X568_splice | Splice Site (SNP) | VAF 8/16 reads (50%) | catalogued as COSV100910656; called by muse, mutect2, varscan2
- NDST3 | c.1216T>A p.F406I | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56619113; called by muse, mutect2, varscan2
- NEB | c.18732G>A p.S6244= | Splice Region (SNP) | VAF 32/63 reads (51%) | catalogued as rs747873337, COSV51360157; called by muse, mutect2, varscan2
- NEB | c.17948G>A p.R5983H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs372699411; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEB | c.16294G>A p.A5432T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.3); catalogued as rs988993094, COSV99427112; called by muse, mutect2, varscan2
- NEDD1 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57146918, COSV99901329; called by muse, mutect2, varscan2
- NEMF | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100028120; called by muse, mutect2, varscan2
- NEUROD6 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51770331; called by muse, mutect2, varscan2
- NFIA | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs1476272721, COSV64539413; called by muse, mutect2, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NKRF | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as COSV100441903; called by muse, mutect2, varscan2
- NLRP5 | c.1654A>G p.M552V | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV101173879; called by muse, mutect2, varscan2
- NOB1 | c.617del p.G206Vfs*4 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | catalogued as rs1214772070, COSV52063007; called by mutect2, pindel, varscan2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs753934412; called by mutect2, varscan2
- NOMO2 | c.1267G>A p.V423I | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as rs777398188, COSV57916204; called by muse, mutect2, varscan2
- NOS1 | c.2027del p.G676Afs*64 | Frame Shift Del (DEL) | VAF 35/74 reads (47%) | catalogued as rs746543323; called by mutect2, varscan2
- NOVA1 | c.101del p.P34Lfs*19 | Frame Shift Del (DEL) | VAF 42/99 reads (42%) | catalogued as rs765756993; called by mutect2, pindel, varscan2
- NPAS4 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1331168354, COSV100215272; called by muse, mutect2, varscan2
- NPIPB3 | c.377C>A p.P126H (on ENST00000542817; = p.P342H on NM_130464.3) | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs371768593, COSV101341653; called by muse, varscan2
- NRAP | c.4949A>G p.Q1650R (on ENST00000359988 / NM_001322945.2; = p.Q1615R on NM_006175.4) | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100668103; called by muse, mutect2, varscan2
- NRM | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV99223932; called by muse, mutect2
- NRP2 | c.252-1G>T p.X84_splice | Splice Site (SNP) | VAF 14/27 reads (52%) | catalogued as COSV99785730; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 38/107 reads (36%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NTRK2 | c.2101G>A p.V701M (on ENST00000323115 / NM_001369534.1; = p.V717M on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52877839; called by muse, mutect2, varscan2
- NUDT17 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100493114; called by muse, mutect2, varscan2
- OAS2 | c.1277del p.N426Tfs*14 | Frame Shift Del (DEL) | VAF 20/49 reads (41%) | catalogued as rs781171419; called by mutect2, pindel, varscan2
- OGFR | c.1882G>T p.G628* | Nonsense Mutation (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99284486; called by muse, mutect2, varscan2
- OPA3 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.423); catalogued as rs913275853, COSV99620161; called by muse, mutect2, varscan2
- OPN5 | c.233G>C p.C78S | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.229); catalogued as COSV55246258, COSV99790052; called by muse, mutect2, varscan2
- OR10H2 | c.145G>A p.V49I | Missense Mutation (SNP) | VAF 79/244 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs139429558; called by muse, mutect2, varscan2
- OR10H5 | c.64del p.H22Tfs*4 | Frame Shift Del (DEL) | VAF 110/248 reads (44%) | catalogued as COSV58277901; called by mutect2, pindel, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 21/158 reads (13%) | catalogued as rs761899382; called by mutect2, varscan2
- OR1L1 | c.482_485del p.D161Vfs*4 (on ENST00000373686; = p.D111Vfs*4 on NM_001005236.3) | Frame Shift Del (DEL) | VAF 28/68 reads (41%) | catalogued as rs772858652; called by pindel, varscan2
- OR2B2 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100308237; called by muse, mutect2, varscan2
- OR2H1 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 32/72 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.225); catalogued as COSV101009938; called by muse, mutect2, varscan2
- OR4C3 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100168301; called by muse, mutect2, varscan2
- OR4F17 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.968); catalogued as rs1336981042, COSV100535590; called by mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52I1 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758198757, COSV56168215; called by muse, mutect2, varscan2
- OR6K2 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV62743590; called by muse, mutect2, varscan2
- OR6T1 | c.925A>G p.R309G | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.156); catalogued as COSV100190191; called by muse, mutect2, varscan2
- ORC2 | c.453G>A p.K151= | Splice Region (SNP) | VAF 32/87 reads (37%) | catalogued as rs1201445216, COSV99309763; called by muse, mutect2, varscan2
- ORC4 | c.284T>C p.L95S | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV99932506; called by muse, mutect2
- OTOGL | c.2333G>A p.G778D (on ENST00000547103; = p.G769D on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766966050, COSV101509512, COSV72007779; called by muse, mutect2, varscan2
- OTOL1 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs938912652, COSV100020274; called by muse, mutect2, varscan2
- P2RX1 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760521423, COSV99844959; called by muse, mutect2, varscan2
- P2RX5 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99835999; called by muse, mutect2
- PACSIN1 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV99763354; called by muse, mutect2, varscan2
- PANK1 | c.938C>T p.P313L (on ENST00000307534 / NM_148977.2; = p.P88L on NM_138316.4) | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100285835; called by muse, mutect2, varscan2
- PAPLN | c.2611del p.H871Tfs*93 (on ENST00000554301; = p.H844Tfs*93 on NM_173462.4) | Frame Shift Del (DEL) | VAF 25/63 reads (40%) | catalogued as rs1291107616; called by mutect2, pindel, varscan2
- PARP1 | c.1519dup p.S507Kfs*14 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | catalogued as rs1159330096; called by mutect2, varscan2
- PATJ | c.4174A>G p.S1392G | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100219991; called by muse, mutect2, varscan2
- PBRM1 | c.2370G>A p.M790I | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.27); catalogued as COSV99968666, COSV99970830; called by muse, mutect2, varscan2
- PCDH10 | c.380T>C p.L127P | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99994573; called by muse, mutect2, varscan2
- PCDHA8 | c.1006G>A p.V336I | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.39); catalogued as COSV65337750; called by muse, mutect2, varscan2
- PCDHGA1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.262); catalogued as rs375344940; called by muse, mutect2, varscan2
- PCDHGA6 | c.1087G>T p.G363* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV99547257; called by muse, mutect2, varscan2
- PCDHGA8 | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.229); catalogued as COSV53896403; called by muse, mutect2, varscan2
- PCSK5 | c.1235A>G p.Q412R | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100950694; called by muse, mutect2, varscan2
- PCSK5 | c.1379C>T p.T460I | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100950693; called by muse, mutect2, varscan2
- PCYT2 | c.1036G>A p.V346I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.137); catalogued as rs142625466; called by muse, mutect2
- PDE7A | c.1179del p.K393Nfs*6 (on ENST00000401827 / NM_001242318.3; = p.K367Nfs*6 on NM_002603.4) | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | catalogued as rs776556726; called by mutect2, varscan2
- PDGFA | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV63280686; called by muse, mutect2
- PDGFRB | c.3034G>A p.V1012M | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as rs757545741, COSV53833936, COSV53844019; called by muse, mutect2, varscan2
- PDZD3 | c.665G>A p.R222Q (on ENST00000531114; = p.R156Q on NM_024791.4) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); catalogued as rs374149447; called by muse, mutect2, varscan2
- PDZRN3 | c.3055G>A p.E1019K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs146957114, COSV55197833; called by muse, mutect2, varscan2
- PEAR1 | c.1575G>T p.P525= | Splice Region (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99442408; called by muse, mutect2, varscan2
- PEX5 | c.718G>A p.A240T | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV99871319; called by muse, mutect2, varscan2
- PGAP4 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs751121272, COSV66388559; called by muse, mutect2, varscan2
- PGBD4 | c.157C>T p.P53S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.857); catalogued as COSV99854991; called by muse, mutect2, varscan2
- PGR | c.2218C>T p.R740* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as rs1315135533, COSV54796997; called by muse, mutect2, varscan2
- PHF13 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs762755982, COSV50010802; called by muse, varscan2
- PLCL1 | c.2913T>A p.Y971* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV101407298; called by muse, mutect2, varscan2
- PLEC | c.2680G>A p.V894I (on ENST00000322810 / NM_201380.4; = p.V784I on NM_000445.5) | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs782595372, COSV59689182; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHA1 | c.476_478del p.E159del | In Frame Del (DEL) | VAF 20/61 reads (33%) | catalogued as rs771030769; called by pindel, varscan2
- PLEKHH3 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 44/64 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV52217128; called by muse, mutect2, varscan2
- PLXNC1 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99313863; called by muse, mutect2, varscan2
- PNISR | c.1130G>A p.S377N | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV100984434; called by muse, mutect2, varscan2
- PNMA3 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as rs781894108, COSV100937673; called by muse, mutect2, varscan2
- POLD1 | c.3293G>A p.R1098H | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs878854552, COSV99570157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLN | c.1036G>T p.G346W | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as COSV101242736; called by muse, mutect2, varscan2
- POR | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101203736; called by muse, mutect2, varscan2
- POT1 | c.826A>G p.R276G | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV62927818; called by muse, mutect2, varscan2
- PPCDC | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777408463, COSV100738949; called by muse, mutect2, varscan2
- PPP1R14D | c.310T>C p.S104P | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1214815930, COSV100146449; called by muse, mutect2, varscan2
- PPP1R18 | c.1207del p.L403Sfs*11 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | catalogued as rs1399344586; called by mutect2, varscan2
- PPP2R5D | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100028406; called by muse, mutect2, varscan2
- PPRC1 | c.755T>A p.V252E | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV99532110; called by muse, mutect2, varscan2
- PPRC1 | c.4217G>A p.R1406Q | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs776919435, COSV53387832; called by muse, mutect2, varscan2
- PQBP1 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 34/74 reads (46%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.511); catalogued as rs781981660, COSV99504575; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- PRDM10 | c.997G>A p.V333M | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.997); catalogued as rs1231347678, COSV58802384; called by muse, mutect2, varscan2
- PRICKLE4 | c.355T>C p.C119R (on ENST00000359201; = p.C159R on NM_013397.6) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV100138914; called by muse, mutect2, varscan2
- PRKDC | c.10814dup p.N3605Kfs*3 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs1284489077; called by mutect2, varscan2
- PRMT2 | c.410C>T p.T137M | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs575840670, COSV99388835; called by muse, mutect2, varscan2
- PRRC2A | c.5649del p.G1884Afs*12 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as COSV52991311; called by mutect2, varscan2
- PRRG4 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs1194344055, COSV99141434; called by muse, mutect2
- PSD | c.750del p.S251Afs*43 | Frame Shift Del (DEL) | VAF 10/97 reads (10%) | catalogued as rs761494960; called by mutect2, pindel
- PSMC4 | c.598dup p.R200Pfs*43 | Frame Shift Ins (INS) | VAF 15/47 reads (32%) | catalogued as rs765768285; called by mutect2, varscan2
- PSTK | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.345); catalogued as COSV100924796; called by muse, mutect2, varscan2
- PTEN | c.302T>A p.I101N | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD110165, CM110135, CX983284, COSV64289692, COSV64297668, COSV64311547; called by muse, mutect2, varscan2
- PTPN3 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); catalogued as COSV99356246; called by muse, mutect2, varscan2
- PTPRT | c.995G>A p.G332D | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100630567; called by muse, mutect2, varscan2
- PVRIG | c.677A>T p.Q226L | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99444096; called by muse, varscan2
- RAB38 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1220806006, COSV99703370; called by muse, mutect2, varscan2
- RAB40B | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs1357435302, COSV99483817; called by muse, mutect2, varscan2
- RABGGTA | c.1339C>T p.H447Y | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV52864209; called by muse, mutect2, varscan2
- RABL6 | c.1829del p.P610Hfs*12 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | catalogued as COSV61039588; called by mutect2, pindel, varscan2
- RAD54L2 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs146155189; called by muse, mutect2, varscan2
- RALGDS | c.1346T>C p.L449P | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100924565; called by muse, mutect2, varscan2
- RANBP2 | c.9356A>G p.D3119G | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV51711004; called by muse, mutect2, varscan2
- RBBP6 | c.2031G>T p.K677N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100154986; called by muse, mutect2, varscan2
- RBL2 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV100044070; called by muse, mutect2
- RBM27 | c.2448del p.K816Nfs*5 | Frame Shift Del (DEL) | VAF 22/58 reads (38%) | catalogued as rs762006287; called by mutect2, varscan2
- RCBTB2 | c.1468_1470del p.E490del | In Frame Del (DEL) | VAF 12/30 reads (40%) | catalogued as rs766802417; called by pindel, varscan2
- RD3 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV100879208; called by muse, mutect2, varscan2
- REST | c.425del p.P142Lfs*94 | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | catalogued as COSV58359464; called by mutect2, pindel
- RFC2 | c.848C>T p.A283V (on ENST00000055077 / NM_181471.3; = p.A249V on NM_002914.4) | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as rs782546413, COSV99278110; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS19 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100180903; called by muse, mutect2, varscan2
- RGS7 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs755739521, COSV100471039; called by muse, mutect2, varscan2
- RHPN2 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 20/99 reads (20%) | catalogued as rs555014775, COSV54285370, COSV99578350; called by muse, mutect2, varscan2
- RIBC2 | c.970G>A p.A324T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs770225912, COSV61581156; called by muse, mutect2
- RNF180 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs141510885; called by muse, mutect2, varscan2
- RNF185 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201108552; called by muse, mutect2, varscan2
- RNF213 | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.7); catalogued as COSV100174001; called by muse, mutect2, varscan2
- RNF213 | c.9023G>A p.C3008Y | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1173029944, COSV60411421; called by muse, mutect2, varscan2
- RNH1 | c.1125C>G p.L375= | Splice Region (SNP) | VAF 25/46 reads (54%) | catalogued as COSV100596879; called by muse, mutect2, varscan2
- ROPN1 | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.933); catalogued as rs1353993818, COSV99481608; called by muse, mutect2, varscan2
- RPAIN | c.562C>A p.P188T | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.073); catalogued as COSV99852257; called by muse, mutect2, varscan2
- RPAP1 | c.4130A>G p.Y1377C | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV99779333; called by muse, mutect2, varscan2
- RPAP1 | c.3464G>A p.R1155H | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs374674439; called by muse, mutect2, varscan2
- RPAP2 | c.1456-1G>A p.X486_splice | Splice Site (SNP) | VAF 27/71 reads (38%) | catalogued as COSV101528688; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 19/41 reads (46%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPS6KA1 | c.1104dup p.S369Qfs*47 | Frame Shift Ins (INS) | VAF 24/61 reads (39%) | catalogued as rs745561139; called by mutect2, varscan2
- RRBP1 | c.3142G>A p.A1048T (on ENST00000377813 / NM_001365613.2; = p.A615T on NM_004587.3) | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.523); catalogued as COSV99854564; called by muse, mutect2, varscan2
- RSPH9 | c.236G>A p.C79Y | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.538); catalogued as COSV100937871; called by muse, mutect2
- RTKN | c.1034C>A p.P345H (on ENST00000272430 / NM_001015055.2; = p.P332H on NM_033046.2) | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as COSV99269831; called by muse, mutect2, varscan2
- RTTN | c.5744dup p.E1916Gfs*6 | Frame Shift Ins (INS) | VAF 24/66 reads (36%) | catalogued as rs756606313; called by mutect2, varscan2
- RUNX1T1 | c.1484G>A p.R495Q (on ENST00000265814 / NM_001198628.1; = p.R468Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs900545909, COSV56152742, COSV56166983; called by muse, mutect2, varscan2
- S100PBP | c.614C>A p.S205Y | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV100758395, COSV63140206; called by muse, mutect2, varscan2
- SAMD9L | c.729C>A p.D243E | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs936333584, COSV100561153; called by muse, mutect2, varscan2
- SBF2 | c.5005G>A p.V1669M | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs757185849, COSV56304189; called by muse, mutect2, varscan2
- SCFD1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.835); catalogued as COSV99249901; called by muse, mutect2, varscan2
- SCUBE3 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1303554759, COSV99235249; called by muse, mutect2
- SELPLG | c.856T>C p.F286L | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.099); catalogued as rs1565888288, COSV99947735; called by muse, mutect2, varscan2
- SEPSECS | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.682); catalogued as COSV100259035; called by muse, mutect2, varscan2
- SEPSECS | c.643G>T p.D215Y | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100259038; called by muse, mutect2, varscan2
- SESN3 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1400088899, COSV53583259; called by muse, mutect2, varscan2
- SETD1A | c.4366G>A p.G1456R | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs1463149845, COSV99353723; called by muse, mutect2, varscan2
- SGCD | c.653C>T p.A218V (on ENST00000435422 / NM_001128209.2; = p.A219V on NM_000337.5) | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV100551160, COSV61919556; called by muse, mutect2, varscan2
- SGSM1 | c.1067G>A p.G356D | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101241172; called by muse, mutect2, varscan2
- SH2B1 | c.700A>G p.S234G | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV100451270; called by muse, mutect2, varscan2
- SH3TC2 | c.1880G>A p.G627D | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs1380546665, COSV100102370; called by muse, mutect2, varscan2
- SHMT1 | c.781G>T p.G261C | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100363680; called by muse, mutect2
- SIK3 | c.2523G>C p.Q841H (on ENST00000445177 / NM_001366686.2; = p.Q799H on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.712); catalogued as COSV99408847; called by muse, mutect2, varscan2
- SIL1 | c.862_864del p.K288del | In Frame Del (DEL) | VAF 22/60 reads (37%) | catalogued as rs148940232; called by pindel, varscan2
- SIN3B | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT tolerated (0.79); PolyPhen benign (0.112); catalogued as rs773679004, COSV99932066; called by muse, mutect2, varscan2
- SKI | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs762750773, COSV101049639; called by muse, varscan2
- SLAMF1 | c.829del p.S277Afs*54 | Frame Shift Del (DEL) | VAF 66/130 reads (51%) | catalogued as rs751442558; called by mutect2, varscan2
- SLC16A11 | c.827del p.G276Dfs*43 (on ENST00000308009; = p.G252Dfs*43 on NM_153357.3) | Frame Shift Del (DEL) | VAF 28/53 reads (53%) | catalogued as COSV99080391; called by mutect2, pindel, varscan2
- SLC17A6 | c.869C>A p.A290E | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.405); catalogued as rs1158568019, COSV99582081, COSV99582439; called by muse, mutect2, varscan2
- SLC24A4 | c.1219G>A p.V407M | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as rs1242929285, COSV100106212, COSV54117121; called by muse, mutect2, varscan2
- SLC2A9 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.679); catalogued as COSV99305610; called by muse, mutect2, varscan2
- SLC35G6 | c.760A>G p.S254G | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.258); catalogued as COSV100263774; called by muse, mutect2, varscan2
- SLC39A11 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV55293996, COSV99724026; called by muse, mutect2, varscan2
- SLC46A3 | c.653T>G p.L218R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99906537; called by muse, mutect2
- SLC4A11 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV101196133; called by muse, mutect2, varscan2
- SLC4A1AP | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100389665; called by muse, varscan2
- SLC5A10 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs531697809, COSV100525532; called by muse, mutect2, varscan2
- SLIT1 | c.2962C>A p.P988T | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99822570; called by muse, mutect2, varscan2
- SLTM | c.1933C>T p.R645* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99989406; called by muse, varscan2
- SLU7 | c.819A>G p.K273= | Splice Region (SNP) | VAF 18/49 reads (37%) | catalogued as COSV99775846; called by muse, mutect2, varscan2
- SLX4 | c.1406del p.P469Hfs*4 | Frame Shift Del (DEL) | VAF 29/69 reads (42%) | catalogued as rs774532876; called by mutect2, pindel, varscan2
- SMARCD1 | c.249del p.N84Tfs*79 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | catalogued as COSV104391003, COSV99948091; called by mutect2, pindel, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 30/85 reads (35%) | catalogued as rs760667210; called by mutect2, varscan2
- SMTN | c.714del p.S239Afs*118 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs747405143; called by mutect2, pindel, varscan2
- SMTNL2 | c.1043C>T p.A348V (on ENST00000389313 / NM_001114974.2; = p.A204V on NM_198501.3) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV58807972; called by muse, mutect2, varscan2
- SNAP91 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99536664; called by muse, mutect2, varscan2
- SNED1 | c.2224C>T p.H742Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.055); catalogued as rs1456310079, COSV100123434; called by muse, mutect2
- SOBP | c.215A>G p.Q72R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100433427; called by muse, mutect2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 40/121 reads (33%) | catalogued as rs371303534; called by mutect2, varscan2
- SPAG9 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT tolerated (0.96); PolyPhen benign (0.027); catalogued as rs768620592, COSV100006023; called by muse, mutect2, varscan2
- SPATA22 | c.803-1G>A p.X268_splice | Splice Site (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99279411; called by muse, mutect2, varscan2
- SPATS2L | c.752A>G p.K251R | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV100660881; called by muse, mutect2, varscan2
- SPDEF | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.084); catalogued as COSV99763355; called by muse, mutect2
- SPEG | c.6697del p.Q2233Rfs*6 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | catalogued as rs752907815; called by pindel, varscan2
- SPTBN5 | c.10235G>A p.R3412H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as rs540346671, COSV100312216; called by muse, varscan2
- SPTBN5 | c.7603C>T p.Q2535* | Nonsense Mutation (SNP) | VAF 32/67 reads (48%) | catalogued as rs767761057, COSV100312218; called by muse, mutect2, varscan2
- SRRM4 | c.1690A>G p.T564A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.173); catalogued as COSV99939445; called by muse, mutect2, varscan2
- SRRT | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs763989148, COSV100730056, COSV61453585; called by muse, mutect2, varscan2
- SSH2 | c.1930G>T p.D644Y | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV99283117; called by muse, mutect2, varscan2
- SSH2 | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV99283119; called by muse, mutect2, varscan2
- SSTR4 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as rs377034050; called by muse, mutect2, varscan2
- STAC2 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.365); catalogued as COSV61065063, COSV61065999; called by muse, mutect2, varscan2
- STAT1 | c.1419G>A p.W473* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100738868; called by muse, mutect2, varscan2
- STAT6 | c.1948G>A p.V650M | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1272933168, COSV100272804; called by muse, mutect2, varscan2
- STRN4 | c.1077C>A p.D359E | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV99624070; called by muse, mutect2, varscan2
- SULT1C2 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs765194303, COSV52266766; called by muse, mutect2, varscan2
- SUPV3L1 | c.1876A>G p.M626V | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100669897; called by muse, mutect2, varscan2
- SYCP1 | c.2376del p.D793Tfs*65 | Frame Shift Del (DEL) | VAF 15/27 reads (56%) | catalogued as rs745637836; called by mutect2, varscan2
- SYCP2 | c.731T>C p.F244S | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100698015; called by muse, mutect2
- SYNE1 | c.10039G>A p.V3347I (on ENST00000367255 / NM_182961.4; = p.V3354I on NM_033071.3) | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs762448899, COSV99579210; called by muse, mutect2, varscan2
- SYNPO2L | c.1006G>A p.D336N (on ENST00000394810 / NM_001114133.3; = p.D112N on NM_024875.5) | Missense Mutation (SNP) | VAF 53/92 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV100866462; called by muse, mutect2, varscan2
- TAF1C | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372871954, COSV58989541; called by muse, mutect2, varscan2
- TAF2 | c.1174C>A p.R392S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100978813; called by muse, mutect2, varscan2
- TAF4 | c.2149C>A p.L717I | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.549); catalogued as COSV99435088; called by muse, mutect2, varscan2
- TBX4 | c.1112del p.P371Lfs*8 | Frame Shift Del (DEL) | VAF 16/71 reads (23%) | catalogued as rs754897911; ClinVar: uncertain significance; called by pindel, varscan2
- TCERG1L | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1256394233, COSV100894592; called by muse, mutect2
- TCF19 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99463293; called by muse, mutect2, varscan2
- TCF4 | c.1940del p.P647Lfs*32 | Frame Shift Del (DEL) | VAF 34/78 reads (44%) | catalogued as COSV61906772; called by mutect2, pindel, varscan2
- TCF4 | c.305-2A>G p.X102_splice | Splice Site (SNP) | VAF 19/46 reads (41%) | catalogued as COSV100610917; called by muse, mutect2, varscan2
- TCIRG1 | c.2395C>T p.H799Y | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99693656; called by muse, mutect2, varscan2
- TDRD5 | c.2374T>C p.W792R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs577467446, COSV54243374; called by muse, mutect2, varscan2
- TECPR1 | c.2983G>A p.G995R | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs765078269, COSV101130480, COSV101130763; called by muse, mutect2, varscan2
- TENM1 | c.2947A>G p.S983G | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV100950976; called by muse, mutect2, varscan2
- TEP1 | c.5960C>T p.A1987V | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs1368307833, COSV99403270; called by muse, mutect2, varscan2
- TET3 | c.2387G>A p.S796N | Missense Mutation (SNP) | VAF 71/138 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.089); catalogued as COSV99996613; called by muse, mutect2, varscan2
- TFAP4 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as COSV52598382; called by muse, mutect2, varscan2
- TFIP11 | c.692G>A p.G231E | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.784); catalogued as COSV101316523; called by muse, mutect2, varscan2
- TGFBR1 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100895457; called by muse, mutect2, varscan2
- THAP7 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs756191065, COSV53145270; called by muse, mutect2, varscan2
- TLE1 | c.140G>A p.C47Y | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as rs1220893779, COSV100916023; called by muse, mutect2, varscan2
- TLE3 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.007); catalogued as rs755315040, COSV100450112, COSV58168888; called by muse, mutect2, varscan2
- TLE4 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs1260079921, COSV54634404; called by muse, mutect2, varscan2
- TLE5 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.34); catalogued as COSV99682377; called by muse, mutect2, varscan2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs754390908; called by mutect2, varscan2
- TMC3 | c.3106C>T p.P1036S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); catalogued as rs1436422553, COSV100846040; called by muse, mutect2, varscan2
- TMEM129 | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.172); catalogued as rs781162476, COSV57559512; called by muse, mutect2, varscan2
- TMEM161A | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773542916, COSV50777931, COSV99365340; called by muse, mutect2, varscan2
- TMEM50A | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100975966; called by muse, mutect2, varscan2
- TMEM59 | c.254A>G p.D85G | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.95); catalogued as COSV99329364; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 46/82 reads (56%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM79 | c.480G>A p.M160I | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99828141; called by muse, mutect2, varscan2
- TMEM8B | c.1186C>T p.L396F | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100941739; called by muse, mutect2, varscan2
- TNFSF12-TNFSF13 | c.493T>C p.C165R | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1443508410, COSV99547438; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNPO3 | c.2074T>C p.Y692H | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV99603498; called by muse, mutect2, varscan2
- TNRC18 | c.4627del p.R1543Afs*13 | Frame Shift Del (DEL) | VAF 47/108 reads (44%) | catalogued as rs754233336; called by mutect2, pindel, varscan2
- TNXB | c.12781T>C p.S4261P (on ENST00000647633; = p.S4014P on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV100926663; called by muse, varscan2
- TOP3A | c.523C>T p.R175* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as rs1163645463, COSV58179529; called by muse, mutect2, varscan2
- TPRA1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs377393713; called by muse, mutect2, varscan2
- TRABD2A | c.1193C>T p.T398M (on ENST00000409520 / NM_001277053.2; = p.T349M on NM_001080824.3) | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs750944359, COSV52849245; called by muse, mutect2, varscan2
- TRIM71 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as rs979021897, COSV67471357; called by muse, mutect2, varscan2
- TRIM9 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs753278189, COSV100032200; called by muse, mutect2, varscan2
- TRIOBP | c.6302T>C p.I2101T (on ENST00000644935 / NM_001039141.3; = p.I388T on NM_007032.5) | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58525714; called by muse, mutect2, varscan2
- TRMT1L | c.196T>C p.S66P | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.245); catalogued as COSV100833544; called by muse, varscan2
- TRPM3 | c.979A>C p.R327= (on ENST00000357533 / NM_001366142.2; = p.R172= on NM_020952.6) | Splice Region (SNP) | VAF 35/73 reads (48%) | catalogued as COSV100625553; called by muse, mutect2, varscan2
- TRPV1 | c.2315G>A p.R772H | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.769); catalogued as rs200898926, COSV99440748; called by muse, mutect2, varscan2
- TSHZ3 | c.2863T>C p.Y955H | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99552797; called by muse, mutect2, varscan2
- TSPAN10 | c.457C>G p.P153A (on ENST00000574882 / NM_001290212.1; = p.P115A on NM_031945.4) | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as rs753180923, COSV60773117; called by muse, mutect2, varscan2
- TTC21B | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99692890; called by muse, mutect2, varscan2
- TTC3 | c.3868C>T p.R1290* | Nonsense Mutation (SNP) | VAF 10/79 reads (13%) | catalogued as rs1485313371, COSV100696056; called by muse, mutect2, varscan2
- TTI1 | c.2995C>A p.L999I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.557); catalogued as COSV100989760; called by muse, mutect2, varscan2
- TTLL5 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as rs367813054; called by muse, mutect2, varscan2
- TTYH2 | c.1391C>T p.T464I | Missense Mutation (SNP) | VAF 63/99 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV99483225; called by muse, mutect2, varscan2
- TUT7 | c.4161A>C p.R1387S | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV99463680; called by muse, mutect2, varscan2
- U2SURP | c.582del p.G195Efs*17 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs1285557136; called by mutect2, varscan2
- UBE2O | c.3150+1G>A p.X1050_splice | Splice Site (SNP) | VAF 5/95 reads (5%) | catalogued as COSV100039569; called by muse, mutect2
- UCK1 | c.829del p.H277Tfs*64 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | catalogued as COSV100586579; called by mutect2, pindel, varscan2
- ULK2 | c.1537C>T p.Q513* | Nonsense Mutation (SNP) | VAF 37/65 reads (57%) | catalogued as COSV100860644; called by muse, mutect2, varscan2
- ULK4 | c.1778del p.K593Rfs*17 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | catalogued as rs76318575; called by mutect2, varscan2
- UNC13A | c.3122G>T p.S1041I | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as COSV99409608; called by muse, mutect2, varscan2
- UNC13D | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs749184121, COSV99257569; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 32/77 reads (42%) | catalogued as rs747493460; called by mutect2, varscan2
- USP7 | c.3244T>C p.F1082L | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100784429; called by muse, mutect2, varscan2
- UTP20 | c.5158C>T p.R1720C | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as rs1196699046, COSV55378613; called by muse, mutect2, varscan2
- UTP4 | c.1081G>T p.G361* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100077162; called by muse, mutect2, varscan2
- VPS13D | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 18/129 reads (14%) | catalogued as COSV100693773; called by muse, mutect2, varscan2
- VPS35L | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs748328502, COSV99221765; called by muse, mutect2, varscan2
- VWA3B | c.3626del p.K1209Rfs*49 | Frame Shift Del (DEL) | VAF 29/71 reads (41%) | catalogued as COSV71368884; called by mutect2, pindel, varscan2
- WDR46 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs775020981, COSV65852088; called by muse, mutect2, varscan2
- WDR72 | c.1580A>G p.E527G | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100855101; called by muse, mutect2, varscan2
- WDR82 | c.317A>G p.H106R | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1310852478, COSV99627237; called by muse, mutect2, varscan2
- WNK2 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474169530, COSV99944756; called by muse, mutect2, varscan2
- XPO4 | c.2546del p.P849Qfs*8 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as COSV55009300; called by mutect2, pindel, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 25/71 reads (35%) | catalogued as rs762052135; called by mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- YIF1A | c.391del p.R131Gfs*50 | Frame Shift Del (DEL) | VAF 9/66 reads (14%) | catalogued as rs761507279; called by pindel, varscan2
- ZBED1 | c.866C>A p.P289H | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV100586084; called by muse, mutect2, varscan2
- ZBTB33 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV100434333; called by muse, mutect2, varscan2
- ZBTB38 | c.3022C>T p.R1008W | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV100376007; called by muse, mutect2, varscan2
- ZBTB4 | c.1004G>T p.R335M | Missense Mutation (SNP) | VAF 69/105 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100263770; called by muse, mutect2, varscan2
- ZBTB7A | c.1378C>T p.H460Y | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100475958; called by muse, mutect2, varscan2
- ZC3H18 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs1224200800, COSV99964447; called by muse, mutect2
- ZC3H3 | c.686G>A p.S229N | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99368613; called by muse, mutect2
- ZC3H4 | c.695A>T p.E232V | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.863); catalogued as COSV99452824; called by muse, varscan2
- ZDHHC16 | c.916_918del p.K306del | In Frame Del (DEL) | VAF 28/104 reads (27%) | catalogued as rs756458996; called by pindel, varscan2
- ZFHX4 | c.10688G>C p.G3563A | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as COSV50793597, COSV99267846; called by muse, mutect2, varscan2
- ZFP36L1 | c.603C>A p.S201R | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100322929; called by muse, mutect2, varscan2
- ZGRF1 | c.6077C>T p.A2026V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101500678, COSV71393521; called by muse, mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF101 | c.784T>C p.F262L | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as COSV100543641; called by muse, mutect2, varscan2
- ZNF106 | c.1444del p.S482Pfs*33 | Frame Shift Del (DEL) | VAF 42/93 reads (45%) | catalogued as rs1198467282, COSV55516091; called by mutect2, varscan2
- ZNF117 | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.232); catalogued as COSV99276120; called by muse, mutect2, varscan2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | catalogued as COSV61506988; called by mutect2, pindel, varscan2
- ZNF2 | c.845G>A p.R282H (on ENST00000611147 / NM_001291605.2; = p.R269H on NM_021088.4) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs767358583, COSV99728500, COSV99728701; called by muse, mutect2, varscan2
- ZNF341 | c.736C>A p.L246I | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV100678068; called by muse, mutect2, varscan2
- ZNF367 | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64546908; called by muse, mutect2, varscan2
- ZNF407 | c.1451G>A p.S484N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99996791; called by muse, mutect2, varscan2
- ZNF407 | c.6664G>A p.V2222M | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs761613021, COSV55274245; called by muse, mutect2, varscan2
- ZNF462 | c.7504G>T p.E2502* | Nonsense Mutation (SNP) | VAF 9/36 reads (25%) | catalogued as COSV52936801, COSV52948274; called by muse, mutect2, varscan2
- ZNF540 | c.807dup p.P270Tfs*5 | Frame Shift Ins (INS) | VAF 15/32 reads (47%) | catalogued as rs763961757; called by mutect2, pindel, varscan2
- ZNF548 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs369371650, COSV60240345; called by muse, mutect2, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF649 | c.918_920del p.V307del | In Frame Del (DEL) | VAF 31/85 reads (36%) | catalogued as rs781194291; called by mutect2, pindel, varscan2
- ZNF665 | c.53C>T p.T18I (on ENST00000600412; = p.T83I on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101128815; called by muse, mutect2, varscan2
- ZNF692 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201441689, COSV60637256; called by mutect2, varscan2
- ZNF704 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 58/121 reads (48%) | catalogued as COSV100589895; called by muse, mutect2, varscan2
- ZNF831 | c.5005G>A p.D1669N | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1295667188, COSV64044824; called by muse, mutect2
- ZNF99 | c.2324C>T p.A775V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV101233764, COSV101233973; called by muse, mutect2, varscan2
- ZRANB3 | c.2135G>A p.G712E | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99924768; called by muse, mutect2, varscan2
- ADAMTS6 | c.1753T>G p.C585G | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRE1 | c.1372del p.D458Ifs*3 | Frame Shift Del (DEL) | VAF 22/73 reads (30%) | called by mutect2, pindel, varscan2
- AHDC1 | c.1758del p.K586Nfs*37 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- ALX4 | c.1016del p.P339Lfs*12 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- ANKRD26 | c.3702del p.K1234Nfs*19 | Frame Shift Del (DEL) | VAF 30/133 reads (23%) | called by mutect2, pindel, varscan2
- ARID1A | c.3524del p.P1175Hfs*5 | Frame Shift Del (DEL) | VAF 26/66 reads (39%) | called by mutect2, pindel, varscan2
- ASB11 | c.68del p.F23Sfs*5 | Frame Shift Del (DEL) | VAF 36/66 reads (55%) | called by mutect2, varscan2
- ATRN | c.2226del p.F742Lfs*59 | Frame Shift Del (DEL) | VAF 29/71 reads (41%) | called by mutect2, pindel, varscan2
- B4GALNT1 | c.1117del p.V373Cfs*28 | Frame Shift Del (DEL) | VAF 19/59 reads (32%) | called by mutect2, pindel, varscan2
- BARD1 | c.513del p.D172Mfs*40 | Frame Shift Del (DEL) | VAF 11/86 reads (13%) | called by mutect2, pindel, varscan2
- BMP8A | c.463del p.H155Tfs*54 | Frame Shift Del (DEL) | VAF 16/86 reads (19%) | called by mutect2, pindel, varscan2
- BORA | c.650del p.K217Sfs*2 (on ENST00000613797; = p.K142Sfs*2 on NM_024808.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- BTAF1 | c.4232dup p.N1411Kfs*16 | Frame Shift Ins (INS) | VAF 11/87 reads (13%) | called by mutect2, pindel, varscan2
- C10orf71 | c.1347dup p.I450Hfs*36 | Frame Shift Ins (INS) | VAF 16/81 reads (20%) | called by mutect2, pindel, varscan2
- CCL4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 114/369 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CCNL2 | c.473dup p.K159Efs*13 | Frame Shift Ins (INS) | VAF 25/86 reads (29%) | called by mutect2, pindel, varscan2
- CCNO | c.793del p.V265Wfs*4 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- CD4 | c.99del p.D35Ifs*5 | Frame Shift Del (DEL) | VAF 36/97 reads (37%) | called by mutect2, pindel, varscan2
- CDSN | c.1409del p.G470Afs*34 | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- CGB8 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); called by mutect2, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 29/108 reads (27%) | called by mutect2, pindel, varscan2
- COQ6 | c.1294del p.R432Gfs*48 | Frame Shift Del (DEL) | VAF 29/58 reads (50%) | called by mutect2, pindel, varscan2
- CROCC | c.5617_5619del p.K1873del | In Frame Del (DEL) | VAF 60/138 reads (43%) | called by mutect2, varscan2
- CSAG3 | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 81/335 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CSNK1D | c.310del p.T104Pfs*9 | Frame Shift Del (DEL) | VAF 31/138 reads (22%) | called by mutect2, pindel, varscan2
- CXCR2 | c.342dup p.G115Wfs*18 | Frame Shift Ins (INS) | VAF 45/107 reads (42%) | called by mutect2, pindel, varscan2
- DBF4 | c.74del p.N25Tfs*5 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- DNAH17 | c.4738del p.R1580Gfs*23 | Frame Shift Del (DEL) | VAF 16/103 reads (16%) | called by mutect2, pindel, varscan2
- EBF3 | c.833del p.G278Vfs*6 (on ENST00000355311 / NM_001375392.1; = p.G269Vfs*6 on NM_001005463.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 31/97 reads (32%) | called by mutect2, pindel, varscan2
- ELF2 | c.884del p.N295Tfs*2 (on ENST00000379550 / NM_001331036.2; = p.N235Tfs*2 on NM_006874.4) | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel, varscan2
- EPPK1 | c.6044del p.G2015Vfs*36 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | called by mutect2, pindel, varscan2
- ERICH6 | c.1197dup p.Q400Sfs*6 | Frame Shift Ins (INS) | VAF 8/54 reads (15%) | called by mutect2, pindel, varscan2
- ESF1 | c.295del p.T99Pfs*12 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by mutect2, pindel, varscan2
- EXO1 | c.424del p.V142* | Frame Shift Del (DEL) | VAF 22/55 reads (40%) | called by mutect2, pindel, varscan2
- F2RL3 | c.1118dup p.S374Qfs*40 | Frame Shift Ins (INS) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- FSTL5 | c.1805dup p.I603Hfs*19 | Frame Shift Ins (INS) | VAF 48/108 reads (44%) | called by mutect2, pindel, varscan2
- GALNT3 | c.79del p.I27Ffs*5 | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | called by mutect2, pindel, varscan2
- GGA1 | c.1181del p.P394Qfs*30 | Frame Shift Del (DEL) | VAF 30/74 reads (41%) | called by mutect2, pindel, varscan2
- GLT8D2 | c.663del p.S222Afs*9 | Frame Shift Del (DEL) | VAF 48/126 reads (38%) | called by mutect2, pindel, varscan2
- GPR171 | c.64del p.Y22Ifs*2 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | called by mutect2, varscan2
- GRB14 | c.612del p.P205Qfs*25 | Frame Shift Del (DEL) | VAF 23/75 reads (31%) | called by mutect2, pindel, varscan2
- GTF2E2 | c.121dup p.T41Nfs*12 | Frame Shift Ins (INS) | VAF 28/64 reads (44%) | called by mutect2, pindel, varscan2
- HSPD1 | c.1387del p.I463Lfs*3 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- HYOU1 | c.1255del p.A419Qfs*14 | Frame Shift Del (DEL) | VAF 11/28 reads (39%) | called by mutect2, varscan2
- IGF2BP3 | c.904del p.I302Lfs*17 | Frame Shift Del (DEL) | VAF 14/95 reads (15%) | called by mutect2, pindel, varscan2
- INPP4B | c.896del p.N299Mfs*10 | Frame Shift Del (DEL) | VAF 37/99 reads (37%) | called by mutect2, pindel, varscan2
- KIDINS220 | c.4417del p.L1473Wfs*35 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- KIR3DL1 | c.365G>T p.R122I | Missense Mutation (SNP) | VAF 66/127 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KRTAP10-10 | c.267del p.C90Afs*177 | Frame Shift Del (DEL) | VAF 47/138 reads (34%) | called by mutect2, pindel, varscan2
- LAMB4 | c.5240del p.N1747Mfs*19 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | called by mutect2, pindel, varscan2
- LMOD3 | c.1583dup p.L529Ifs*23 | Frame Shift Ins (INS) | VAF 34/95 reads (36%) | called by mutect2, pindel, varscan2
- MANEA | c.831del p.K277Nfs*6 | Frame Shift Del (DEL) | VAF 32/77 reads (42%) | called by mutect2, pindel, varscan2
- MAP3K2 | c.120del p.K40Nfs*29 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | called by mutect2, varscan2
- MAP7D3 | c.922del p.Q308Rfs*2 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- MARK3 | c.256del p.I86* | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, varscan2
- MED4 | c.25_27del p.K9del | In Frame Del (DEL) | VAF 60/124 reads (48%) | called by mutect2, pindel, varscan2
- MYO3A | c.1588del p.Y530Tfs*13 | Frame Shift Del (DEL) | VAF 31/61 reads (51%) | called by mutect2, pindel, varscan2
- NBPF11 | c.328del p.R110Gfs*14 | Frame Shift Del (DEL) | VAF 33/162 reads (20%) | called by mutect2, pindel, varscan2
- NEIL1 | c.570del p.F191Lfs*20 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- NEK8 | c.898dup p.R300Pfs*109 | Frame Shift Ins (INS) | VAF 84/144 reads (58%) | called by mutect2, varscan2
- NLGN3 | c.2146dup p.A716Gfs*7 (on ENST00000358741 / NM_181303.2; = p.A696Gfs*7 on NM_018977.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- NPAT | c.1642del p.S548Vfs*11 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
285 further variants in this file (41 protein-altering or splice-affecting, 221 silent, 23 other) are not listed here.
